Surgical pathology report (de-identified scan), TCGA case TCGA-CS-6290, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-6290-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Left temporal tumor : ANAPLASTIC ASTROCYTOMA, WHO GRADE iii. SEE MICROSCOPIC DESCRIPTION.
2. SPECIMEN NOT RECEIVED:
3. Left temporal tumor: ASTROCYTIC NEOPLASM CONSISTENT WITH PORTION OF ANAPLASTIC ASTROCYTOMA. SEE DIAGNOSES FOR SPECIMENS #1 AND #3.
4. Left temporal tumor: ANAPLASTIC ASTROCYTOMA, WHO GRADE iii. SEE MICROSCOPIC DESCRIPTION.

[REDACTED]
[REDACTED]
This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor is composed of moderately pleomorphic neoplastic astrocytes. While mitotic figures are not numerous, multiple tumor mitotic figures are identified. Mitotic figures are identified in specimen #1 and on slide 4B. The percentage of cells showing positive nuclear staining on Ki67 immunohistochemical stain varies through out the slides stained. However, areas of tumor on slide 1B show positive Ki67 immunohistochemical staining in up to 10% of tumor cell nuclei.

No tumor necrosis is identified. No endothelial proliferation is identified.

Synaptophysin immunohistochemical staining shows positive staining of neuropil. Neu-N immunohistochemical stain shows positive staining of cortical neurons surrounded by tumor cells. No ganglion cell component of the tumor is identified.

Case reviewed in conference with [REDACTED]

Frozen Section Diagnosis:

[REDACTED]

[page 2 of 5]
1. Left temporal tumor: Glioma, no definite high-grade features identified on representative frozen section. Frozen section diagnosis discussed with [REDACTED] Frozen section diagnosis by [REDACTED]

3. Left temporal tumor: No frozen section performed on #3 as per [REDACTED]

Clinical History and Diagnosis:
Glioma

Source of Specimen:

- 1: Left temporal tumor
- 2: SPECIMEN NOT RECEIVED
- 3: Left temporal tumor
- 4: Left temporal tumor

Gross Description:

1. Left temporal tumor: Received fresh for frozen section, in a specimen container labeled with the patient's name and "#1 left temporal tumor with consistent with low-grade glioma", is a 1 x 1 x 0.2 cm aggregate of soft tan-pink tissue. Frozen sections are prepared. Touch preparations are made. Approximately 50% of the specimen is submitted for frozen section analysis. The remainder of the specimen is entirely submitted in 2 cassettes as follows:

- A. frozen section control
- B. remainder of specimen

2. SPECIMEN NOT RECEIVED:

3. Left temporal tumor: Received fresh, in a specimen container labeled with the patient's name and "#3 left temporal tumor", is a 1 x 1 x 0.3 cm aggregate of soft tan-pink tissue. The entire specimen is submitted in 2 cassettes.

4. Left temporal tumor: Received in formalin, in a specimen container labeled with the patient's name and "#4 left temporal tumor for permanent", are 2 irregular fragments of soft tan-pink tissue ranging in size from 1-2 cm. The larger fragment is sectioned. The entire specimen is submitted in 2 cassettes.

Histology Laboratory

[page 3 of 5]
[REDACTED]

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of [REDACTED] Applied Immunohistochemistry, [REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED] et.al. [REDACTED]
[REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the Clinical Laboratory of [REDACTED]
[REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[REDACTED]

[page 4 of 5]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 5 of 5]
one with a 1p/1q probe/control pair and one with a 19q/19p probe/control pair. The 19q and 1p probes map to regions that are commonly deleted in gliomas. The nuclei are counterstained with DAPI and the cells examined by epi-fluorescence microscopy. The total number of counts for each probe is determined in 200 cells and the ratios of 1p/1q and 19q/19p are calculated.

Normal range: The normal ratio is approximately 1. Any ratio > 0.80 is considered normal.

LIMITATIONS: Low levels of malignant cells in the specimen can result in a false negative result. As with all laboratory tests, sampling error and other factors may affect the outcome of the assay. Correlation of results with other clinical and laboratory data should be obtained.

COMMENT: This test was developed and its performance characteristics determined by the Molecular Pathology Laboratory at [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration.

This test is not to be used as a diagnostic procedure without confirmation of the diagnosis by another medically established product or procedure.

Clinical History and Diagnosis:

Anaplastic Astrocytoma, WHO Grade III

Source of Specimen:
1: FISH-TISSUE

Gross Description:
[REDACTED]
Formalin fixed paraffin-embedded tissue

Histology Laboratory
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 313ea572-cfd4-4ab5-b4cd-16556eac0fe6 (TCGA-CS-6290.4D5BDF18-7799-463D-A33A-BEB8322B0621.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).